Somatic mutation profile of tumor specimen d4afb9cf-2f90-44b9-bd60-d03069 (aliquot d4afb9cf-2f90-44b9-bd60-d03069_D10) from CPTAC case 11CO059, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen d4afb9cf-2f90-44b9-bd60-d03069: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9656f821-4d3c-464c-adf2-7a6c148b17ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4c4918cc-e239-4894-9deb-535e21 (Blood Derived Normal), aliquot 4c4918cc-e239-4894-9deb-535e21_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ceac5b1-a55d-470d-a55a-aa2a861d7e7e

The open-access MAF lists 4,126 somatic variants for this specimen: 2,795 protein-altering or splice-affecting, 840 silent, 491 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,087, Silent 840, Frame Shift Del 433, Intron 268, Frame Shift Ins 85, Nonsense Mutation 81, 3'UTR 70, Splice Site 56, 5'UTR 53, RNA 41, Splice Region 41, 5'Flank 36.

Variants (750 of 4,126; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs128621204, CM940202, COSV104394470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.6354C>T p.I2118= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs112989722, CM074799, CS971734, COSV57314794; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- IQSEC2 | c.2983C>T p.R995W (on ENST00000642864 / NM_001111125.3; = p.R790W on NM_015075.2) | Missense Mutation (SNP) | VAF 86/594 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057521657, COSV64723299; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 15/118 reads (13%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KRT5 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 80/466 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs61297109, CM045867, CM103083, CM930459, COSV52860636; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- L1CAM | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852525, CM970859, COSV62830040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LDLR | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 69/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922571, CM060316, CM095448, CM127528; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5930C>T p.T1977I | Missense Mutation (SNP) | VAF 31/145 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 17/105 reads (16%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- POLG | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 74/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052887, CM033445, CM117636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RECQL4 | c.1015del p.L339Cfs*20 | Frame Shift Del (DEL) | VAF 80/516 reads (16%) | catalogued as rs1060501384; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SEC63 | c.1605del p.K535Nfs*28 | Frame Shift Del (DEL) | VAF 24/115 reads (21%) | catalogued as rs752868449; ClinVar: pathogenic; called by mutect2, varscan2
- TPO | c.2421dup p.C808Lfs*72 | Frame Shift Ins (INS) | VAF 96/660 reads (15%) | catalogued as rs760307139; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 40/230 reads (17%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A1BG | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.411); catalogued as rs1012810499; called by muse, mutect2, varscan2
- AADAT | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1388012625; called by muse, mutect2, varscan2
- ABCA6 | c.2554A>G p.T852A | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs934765000; called by muse, mutect2, varscan2
- ABCB5 | c.3079C>T p.R1027C (on ENST00000404938 / NM_001163941.2; = p.R582C on NM_178559.6) | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773162567, COSV51704137; called by muse, mutect2, varscan2
- ABCC1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749166736, COSV60687702; called by muse, mutect2, varscan2
- ABCC11 | c.3436T>C p.Y1146H | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1334620985; called by muse, mutect2, varscan2
- ABHD16B | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs768118976, COSV99410673; called by muse, mutect2
- ABR | c.2526dup p.I843Hfs*46 (on ENST00000302538 / NM_021962.5; = p.I806Hfs*46 on NM_001092.5) | Frame Shift Ins (INS) | VAF 77/240 reads (32%) | catalogued as rs750897785; called by mutect2, varscan2
- AC069544.2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs1400856132; called by muse, mutect2, varscan2
- ACACB | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs753641748, COSV58130639; called by muse, mutect2, varscan2
- ACADVL | c.1679-7C>T | Splice Region (SNP) | VAF 76/407 reads (19%) | catalogued as rs776276526; called by muse, mutect2, varscan2
- ACCS | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1449695415, COSV55460264; called by muse, mutect2, varscan2
- ACOT11 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs756350482; called by muse, mutect2, varscan2
- ACTC1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV51761249; called by muse, mutect2, varscan2
- ACTN2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370689695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM29 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs764489055; called by muse, mutect2, varscan2
- ADAMTS16 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746897394; called by muse, mutect2, varscan2
- ADAMTS9 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373729997; called by muse, mutect2, varscan2
- ADAT1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462755168; called by muse, mutect2, varscan2
- ADCY3 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV53170053; called by muse, mutect2, varscan2
- ADCY6 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs747065337, COSV57166667; called by muse, mutect2, varscan2
- ADD3 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53321811; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB1 | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs377716870, COSV60099809; called by muse, mutect2
- ADGRB2 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57071881; called by muse, varscan2
- ADGRB2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751147414; called by muse, mutect2, varscan2
- ADGRB3 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369343391; called by mutect2, varscan2
- ADGRF5 | c.1993del p.E665Kfs*9 | Frame Shift Del (DEL) | VAF 44/319 reads (14%) | catalogued as COSV51938393; called by mutect2, pindel, varscan2
- ADGRG4 | c.6337A>G p.I2113V | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1569325085; called by muse, mutect2
- ADGRG7 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1391656229; called by muse, mutect2
- ADGRV1 | c.16226G>A p.R5409Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs567881943; ClinVar: uncertain significance; called by mutect2, varscan2
- ADI1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1329009676, COSV100537866, COSV59377534; called by muse, mutect2, varscan2
- ADNP2 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 66/438 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.213); catalogued as rs765094493; called by muse, mutect2, varscan2
- ADPRHL1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310247236; called by muse, mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs1554870245; called by mutect2, pindel, varscan2
- ADRA2C | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.498); catalogued as rs1176787969; called by muse, mutect2, varscan2
- ADRB1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs72556521; called by muse, mutect2, varscan2
- AHNAK2 | c.11225A>G p.D3742G | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1470793464; called by muse, mutect2, varscan2
- AHSG | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 75/410 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs548302489, COSV56609041; called by muse, mutect2, varscan2
- AKAP13 | c.6599G>A p.R2200H (on ENST00000394518 / NM_007200.5; = p.R2204H on NM_006738.6) | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs531745352, COSV63449825; called by muse, mutect2, varscan2
- AKAP6 | c.4238T>G p.F1413C | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.41); catalogued as COSV55206290; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALOX5 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1425770103; called by muse, mutect2, varscan2
- ALPK3 | c.62del p.G21Afs*88 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs1250475254; called by mutect2, pindel
- ALS2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 42/302 reads (14%) | catalogued as rs1340248169, COSV51890645; called by muse, mutect2, varscan2
- AMBP | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs761457908, COSV54323850; called by muse, mutect2, varscan2
- AMMECR1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs374049534, COSV53320812; called by muse, mutect2, varscan2
- ANGEL2 | c.642C>T p.D214= | Splice Region (SNP) | VAF 11/79 reads (14%) | catalogued as rs1318215998, COSV64738414; called by muse, mutect2, varscan2
- ANK3 | c.10795A>G p.N3599D | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55055440; called by muse, mutect2, varscan2
- ANKDD1A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs374847520; called by muse, mutect2, varscan2
- ANKRD13B | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801405; called by muse, mutect2, varscan2
- ANKRD24 | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1370484629; called by muse, mutect2, varscan2
- ANKRD35 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100841744; called by muse, mutect2, varscan2
- ANKRD54 | c.476-2A>G p.X159_splice | Splice Site (SNP) | VAF 28/180 reads (16%) | catalogued as COSV53236440; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- AP002748.5 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 95/568 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs971605369; called by muse, mutect2, varscan2
- AP1M2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs1490195492; called by muse, mutect2, varscan2
- AP1S1 | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV61760874; called by muse, mutect2, varscan2
- AP2A1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100756092; called by muse, mutect2
- AP3B1 | c.3274T>C p.S1092P | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54875763; called by muse, mutect2
- AP3D1 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1383448509; called by muse, mutect2, varscan2
- APC | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as COSV57343637; called by muse, mutect2, varscan2
- APC | c.5936A>G p.N1979S | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as CD130108, COSV57330653; called by muse, mutect2, varscan2
- APLP1 | c.1930T>C p.Y644H (on ENST00000221891 / NM_001024807.3; = p.Y643H on NM_005166.4) | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55703069; called by muse, mutect2, varscan2
- APOB | c.6430G>T p.A2144S | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as COSV51942987; called by muse, mutect2, varscan2
- ARC | c.433C>A p.R145S | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as rs867095273, COSV63079185; called by muse, mutect2, varscan2
- ARFGEF2 | c.1487G>A p.R496K | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147345525; called by muse, mutect2, varscan2
- ARHGAP24 | c.2179T>C p.S727P (on ENST00000395184 / NM_001025616.3; = p.S634P on NM_031305.3) | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51990552; called by muse, mutect2, varscan2
- ARHGAP30 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs377157727; called by muse, mutect2, varscan2
- ARHGAP31 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs760373610, COSV51798106, COSV99956814; called by muse, mutect2, varscan2
- ARHGEF17 | c.4283C>T p.A1428V | Missense Mutation (SNP) | VAF 100/636 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs747200440; called by muse, mutect2, varscan2
- ARHGEF17 | c.6127G>A p.G2043S | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs368547430; called by mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 52/282 reads (18%) | catalogued as rs758608743; called by mutect2, varscan2
- ASB10 | c.715del p.A239Hfs*145 (on ENST00000420175 / NM_001142459.2; = p.A224Hfs*145 on NM_080871.4) | Frame Shift Del (DEL) | VAF 73/436 reads (17%) | catalogued as rs750715799; called by mutect2, pindel, varscan2
- ASB13 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754407925, COSV100731401, COSV63091662; called by muse, varscan2
- ASCC3 | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100226501; called by muse, mutect2
- ASL | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs200853731, COSV59189183; called by muse, mutect2, varscan2
- ASMTL | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); catalogued as rs1472476331; called by muse, mutect2, varscan2
- ASMTL | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1349311941, COSV101187777; called by muse, mutect2, varscan2
- ASPN | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100978648; called by muse, mutect2, varscan2
- ASTN2 | c.1730A>G p.Q577R (on ENST00000313400 / NM_001365069.1; = p.Q526R on NM_014010.5) | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57757354; called by muse, mutect2, varscan2
- ATCAY | c.780-1G>T p.X260_splice | Splice Site (SNP) | VAF 37/190 reads (19%) | catalogued as COSV56656458; called by muse, mutect2, varscan2
- ATP10D | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as rs753004084, COSV56705902; called by muse, mutect2, varscan2
- ATP13A1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317420776, COSV52283870; called by muse, mutect2, varscan2
- ATP1A4 | c.2218A>G p.M740V | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs749181324; called by muse, mutect2, varscan2
- ATP1B4 | c.912C>T p.H304= (on ENST00000218008 / NM_001142447.3; = p.H300= on NM_012069.5) | Splice Region (SNP) | VAF 31/222 reads (14%) | catalogued as rs368849098; called by muse, mutect2, varscan2
- ATP6V0A1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs545345712, COSV52874096, COSV99231429; called by mutect2, varscan2
- ATP6V0A4 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs142011055; called by muse, mutect2, varscan2
- ATP8A2 | c.1967G>T p.R656I | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54947656; called by muse, mutect2, varscan2
- AURKC | c.430G>A p.A144T (on ENST00000302804 / NM_001015878.2; = p.A110T on NM_003160.3) | Missense Mutation (SNP) | VAF 29/533 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57140504; called by muse, mutect2
- AUTS2 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs555021087, COSV61398839; called by muse, mutect2, varscan2
- B4GALNT1 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs201263683, COSV62041310; called by muse, mutect2, varscan2
- BACH2 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 107/634 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57590256; called by muse, mutect2, varscan2
- BACH2 | c.1402G>C p.V468L | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV57601712; called by muse, mutect2
- BAK1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 93/423 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.466); catalogued as rs761535491; called by muse, mutect2, varscan2
- BAP1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs771326820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS9 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184994140, COSV54164370; called by muse, mutect2, varscan2
- BCDIN3D | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777009576, COSV100445598; called by muse, mutect2, varscan2
- BCL11A | c.1891G>T p.A631S (on ENST00000335712 / NM_001365609.1; = p.A665S on NM_018014.4) | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100185202; called by muse, varscan2
- BCL2L2-PABPN1 | c.1088C>T p.S363F (on ENST00000678502; = p.S331F on NM_001199864.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.091); catalogued as COSV99391251; called by muse, mutect2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 30/257 reads (12%) | catalogued as rs758526156; called by mutect2, varscan2
- BCL9L | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs372773894; called by muse, mutect2, varscan2
- BCLAF1 | c.1373del p.N458Ifs*10 | Frame Shift Del (DEL) | VAF 31/230 reads (13%) | catalogued as rs755078065; called by mutect2, pindel, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs752427670; called by mutect2, varscan2
- BEAN1 | c.599C>T p.P200L (on ENST00000536005 / NM_001178020.3; = p.P91L on NM_001136106.5) | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1004333572, COSV100227830; called by muse, mutect2, varscan2
- BEND5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.2); catalogued as rs200112741; called by mutect2, varscan2
- BHLHA15 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV52003095; called by muse, mutect2
- BICRA | c.2281del p.Q761Rfs*8 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | catalogued as rs1350784790; called by mutect2, pindel
- BICRA | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.168); catalogued as rs1008350096; called by muse, mutect2, varscan2
- BICRAL | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as rs143401966; called by muse, mutect2, varscan2
- BID | c.253G>A p.A85T (on ENST00000317361 / NM_197966.2; = p.A39T on NM_001196.4) | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs372024838; called by muse, mutect2, varscan2
- BMP15 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140319105, COSV99399328, COSV99399360; called by muse, mutect2, varscan2
- BMP2K | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs372259794; called by muse, mutect2, varscan2
- BMP7 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67780993; called by muse, mutect2, varscan2
- BMP7 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 113/709 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs771679633, COSV67780443; called by muse, mutect2, varscan2
- BMPER | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.535); catalogued as rs1412919608, COSV99779087; called by mutect2, varscan2
- BNIP5 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs1398346651; called by muse, mutect2, varscan2
- BRSK1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378692450, COSV100474017; called by muse, mutect2, varscan2
- BSN | c.6649C>T p.R2217W | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760545184; called by muse, mutect2, varscan2
- C11orf95 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV58032446; called by muse, mutect2, varscan2
- C12orf56 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs778970671; called by muse, mutect2, varscan2
- C16orf78 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs144505396; called by muse, mutect2, varscan2
- C1QL4 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.752); catalogued as rs771733570; called by muse, mutect2, varscan2
- C20orf202 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1014309242, COSV101272491; called by muse, mutect2, varscan2
- C2CD2L | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380523813, COSV100371453; called by muse, mutect2, varscan2
- C2orf74 | c.107del p.L36Yfs*25 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs1265298443; called by mutect2, pindel, varscan2
- C3orf38 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59628946; called by muse, mutect2, varscan2
- C3orf56 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs928760610; called by muse, mutect2, varscan2
- C7orf31 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as rs1392083594, COSV52217022; called by muse, mutect2, varscan2
- CACNA1E | c.4334C>T p.A1445V | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62387510; called by muse, mutect2, varscan2
- CACNA1I | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); catalogued as rs768104592; called by muse, varscan2
- CACNB2 | c.415G>A p.A139T (on ENST00000324631 / NM_201596.3; = p.A84T on NM_000724.4) | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs886039055, COSV56614832; called by muse, mutect2
- CAMSAP2 | c.2974A>G p.N992D (on ENST00000236925 / NM_001297707.2; = p.N981D on NM_203459.3) | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV52674084; called by muse, varscan2
- CAMSAP2 | c.3019C>T p.R1007W (on ENST00000236925 / NM_001297707.2; = p.R996W on NM_203459.3) | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs1245032037, COSV52679069; called by muse, varscan2
- CAND2 | c.3122A>G p.N1041S (on ENST00000456430 / NM_001162499.2; = p.N924S on NM_012298.3) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs764659354; called by muse, mutect2, varscan2
- CAPN1 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs375107477; called by muse, mutect2, varscan2
- CAPN10 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs2975765; called by muse, mutect2, varscan2
- CAPN13 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs748992413, COSV54429760; called by muse, mutect2, varscan2
- CAPN14 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.439); catalogued as rs532403679; called by muse, mutect2, varscan2
- CARD10 | c.1150G>C p.V384L | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs760911423; called by muse, mutect2, varscan2
- CARD14 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746260783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARMIL2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1270112047; called by muse, mutect2, varscan2
- CARMIL2 | c.1253dup p.Q419Afs*112 | Frame Shift Ins (INS) | VAF 38/260 reads (15%) | catalogued as rs764374356; called by pindel, varscan2
- CARMIL3 | c.4003C>T p.R1335W | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs768605232; called by muse, varscan2
- CARMIL3 | c.4015del p.L1339* | Frame Shift Del (DEL) | VAF 38/250 reads (15%) | catalogued as rs1167529280; called by pindel, varscan2
- CASP5 | c.846dup p.P283Tfs*7 | Frame Shift Ins (INS) | VAF 98/624 reads (16%) | catalogued as rs528109898; called by mutect2, pindel, varscan2
- CATSPER4 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386576322, COSV58794346; called by muse, varscan2
- CATSPERB | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as rs760324197, COSV56428237; called by muse, mutect2, varscan2
- CC2D1B | c.1341del p.I448Sfs*122 | Frame Shift Del (DEL) | VAF 29/194 reads (15%) | catalogued as rs777168041; called by mutect2, pindel, varscan2
- CCDC105 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV52964427; called by muse, mutect2, varscan2
- CCDC106 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.572); catalogued as rs150361758; called by muse, mutect2, varscan2
- CCDC71 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1006250262; called by muse, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 26/166 reads (16%) | catalogued as rs747131147; called by pindel, varscan2
- CCDC8 | c.890del p.G297Efs*12 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | catalogued as rs1450099223; called by mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 42/240 reads (18%) | catalogued as rs773752200; called by mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | catalogued as rs781790231; called by mutect2, varscan2
- CCNB3 | c.4072T>C p.Y1358H | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.066); catalogued as COSV52081180; called by muse, mutect2, varscan2
- CCR6 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs376263394; called by muse, mutect2, varscan2
- CCR9 | c.784G>A p.V262I (on ENST00000357632 / NM_031200.3; = p.V250I on NM_006641.4) | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs202070482; called by muse, mutect2, varscan2
- CD151 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs755504233; called by muse, mutect2, varscan2
- CD163 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 40/467 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1322862177; called by muse, mutect2
- CD163L1 | c.2526A>G p.I842M | Missense Mutation (SNP) | VAF 71/555 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV58013794; called by muse, mutect2, varscan2
- CD22 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.402); catalogued as rs779809517, COSV50051240; called by muse, mutect2, varscan2
- CD248 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs771006213; called by muse, mutect2
- CD82 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV57033987; called by muse, mutect2, varscan2
- CDC14C | c.1058C>A p.A353D (on ENST00000428251; = p.A246D on NM_152627.3) | Missense Mutation (SNP) | VAF 75/623 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1326729700; called by muse, varscan2
- CDC27 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765736331, COSV50680201; called by mutect2, varscan2
- CDC42BPA | c.3901C>T p.R1301* (on ENST00000334218 / NM_001366019.2; = p.R1288* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/201 reads (14%) | catalogued as rs760385271, COSV100504301; called by muse, mutect2, varscan2
- CDC42BPA | c.2084dup p.K696Efs*6 | Frame Shift Ins (INS) | VAF 16/160 reads (10%) | catalogued as rs869225809; called by mutect2, pindel
- CDH10 | c.2152C>A p.L718I | Missense Mutation (SNP) | VAF 67/403 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); catalogued as COSV52582162; called by muse, mutect2, varscan2
- CDH10 | c.322del p.T108Qfs*30 | Frame Shift Del (DEL) | VAF 42/290 reads (14%) | catalogued as rs748395403; called by pindel, varscan2
- CDH12 | c.1669T>A p.Y557N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV101201625; called by muse, mutect2
- CDH15 | c.1537dup p.H513Pfs*144 | Frame Shift Ins (INS) | VAF 61/518 reads (12%) | catalogued as rs763850576; called by mutect2, varscan2
- CDH26 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as rs754473936; called by muse, mutect2, varscan2
- CDH8 | c.1536+6T>A | Splice Region (SNP) | VAF 9/85 reads (11%) | catalogued as COSV54848692; called by muse, mutect2
- CDH8 | c.1199T>G p.V400G | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54872943; called by muse, mutect2, varscan2
- CDHR1 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753458279; called by muse, mutect2
- CDK5RAP3 | c.936G>T p.W312C | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621076; called by muse, mutect2, varscan2
- CDK6 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as rs902137115, COSV56008604; called by muse, mutect2, varscan2
- CDRT15L2 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.497); catalogued as rs571414684; called by muse, mutect2, varscan2
- CDS1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs1390432618; called by muse, mutect2, varscan2
- CDYL2 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV73647836; called by muse, mutect2, varscan2
- CEACAM4 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs557074639, COSV99700991; called by muse, mutect2, varscan2
- CELSR3 | c.9532C>T p.R3178W | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs758292109, COSV50873748; called by muse, mutect2, varscan2
- CELSR3 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775718093; called by muse, mutect2, varscan2
- CEP295 | c.5045dup p.S1683Kfs*2 | Frame Shift Ins (INS) | VAF 34/180 reads (19%) | catalogued as rs762289202; called by mutect2, varscan2
- CFAP69 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1260822682, COSV100290157; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 23/167 reads (14%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHFR | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs752932212; called by muse, varscan2
- CHMP1B | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs1256462232; called by muse, mutect2, varscan2
- CHPF2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50388916; called by muse, mutect2, varscan2
- CHPF2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367738644; called by muse, mutect2, varscan2
- CHRM5 | c.820T>G p.S274A | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.856); catalogued as COSV67248010; called by muse, mutect2, varscan2
- CIAO3 | c.1193-1G>T p.X398_splice | Splice Site (SNP) | VAF 48/307 reads (16%) | catalogued as rs754183985, COSV52402694; called by muse, mutect2, varscan2
- CILK1 | c.1444C>T p.R482W (on ENST00000350082 / NM_001375397.1; = p.R475W on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/406 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs377606328, COSV63153904; called by muse, varscan2
- CILP2 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs902185958, COSV52272671; called by muse, mutect2
- CILP2 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764372845, COSV52277292; called by muse, mutect2, varscan2
- CKLF | c.449_451del p.E150del (on ENST00000264001 / NM_016951.4; = p.E65del on NM_016326.3) | In Frame Del (DEL) | VAF 38/256 reads (15%) | catalogued as rs752594509; called by pindel, varscan2
- CKMT2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs576895568; called by muse, mutect2, varscan2
- CLCA1 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 53/262 reads (20%) | catalogued as COSV52330657; called by muse, mutect2, varscan2
- CLN5 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs367952803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLPTM1L | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs752193453, COSV57989902; called by muse, mutect2, varscan2
- CLUH | c.2116G>A p.G706S (on ENST00000435359; = p.G745S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs745874735; called by muse, mutect2, varscan2
- CNNM1 | c.102del p.P36Rfs*198 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | catalogued as COSV63201363; called by mutect2, pindel, varscan2
- CNOT4 | c.1656G>A p.M552I (on ENST00000315544 / NM_001190848.1; = p.M549I on NM_001008225.2) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1200644808; called by muse, mutect2
- CNOT6 | c.665del p.K222Rfs*8 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | catalogued as rs1216950236, COSV99993855; called by mutect2, pindel, varscan2
- CNTLN | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1378979662; called by muse, mutect2, varscan2
- CNTN1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 62/476 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs1451321171, COSV61646803; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 52/169 reads (31%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COG5 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 26/728 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99709236; called by muse, mutect2
- COL11A1 | c.4216C>T p.P1406S | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1254540628; called by muse, mutect2, varscan2
- COL12A1 | c.1451A>G p.Y484C | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486178; called by muse, mutect2, varscan2
- COL18A1 | c.2743G>T p.G915C (on ENST00000359759 / NM_130444.3; = p.G680C on NM_030582.4) | Missense Mutation (SNP) | VAF 143/872 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62702268; called by muse, mutect2, varscan2
- COL19A1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753339843, COSV100505938, COSV59571242; called by muse, mutect2, varscan2
- COL20A1 | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs375353757; called by muse, mutect2, varscan2
- COL4A2 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs199875726; called by muse, mutect2
- COL4A4 | c.3943C>G p.P1315A | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61630789; called by muse, mutect2, varscan2
- COL5A1 | c.5266G>A p.A1756T | Missense Mutation (SNP) | VAF 132/859 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs769947722; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A2 | c.2959A>G p.T987A | Missense Mutation (SNP) | VAF 59/590 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1046937114; called by muse, mutect2
- COLEC11 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as rs778792218, COSV52596391; called by muse, mutect2, varscan2
- COPA | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as COSV99616929; called by muse, mutect2, varscan2
- COPB1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1000680755; called by muse, mutect2
- COPS5 | c.921-5del | Splice Region (DEL) | VAF 18/55 reads (33%) | catalogued as rs200155628; called by mutect2, varscan2
- CRACDL | c.384A>G p.I128M | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1461615549; called by muse, mutect2, varscan2
- CRIPT | c.132del p.A45Qfs*86 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs771238795; called by mutect2, pindel, varscan2
- CRTAC1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs202124986; called by muse, mutect2, varscan2
- CRTC1 | c.1277del p.P426Qfs*85 | Frame Shift Del (DEL) | VAF 42/227 reads (19%) | catalogued as rs760791352; called by mutect2, pindel, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 51/327 reads (16%) | catalogued as rs747437399; called by mutect2, varscan2
- CSMD2 | c.6442G>A p.E2148K | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99594704; called by mutect2, varscan2
- CTDP1 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 61/587 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.318); catalogued as COSV50002219; called by muse, mutect2, varscan2
- CTNNA3 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs1393142163; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTU1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1478999180; called by muse, varscan2
- CUL1 | c.1210A>G p.N404D | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749259569; called by muse, mutect2, varscan2
- CUX1 | c.2590C>T p.R864W | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs896592566; called by muse, mutect2, varscan2
- CUX1 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs782570023, COSV52894328; called by muse, varscan2
- CYB5R3 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs547268043, COSV61545655; called by muse, mutect2, varscan2
- CYB5RL | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 30/180 reads (17%) | catalogued as rs903416654; called by muse, mutect2, varscan2
- CYP2B6 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1196290325; called by muse, mutect2, varscan2
- CYP4F12 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs577314511, COSV61175366; called by mutect2, varscan2
- CYP4F8 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs766290409, COSV57854021; called by muse, mutect2, varscan2
- CYP7A1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV56965283; called by muse, mutect2, varscan2
- CYTH4 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs200267703, COSV50632119; called by muse, mutect2, varscan2
- CYTL1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs1440843551; called by muse, mutect2, varscan2
- DBP | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 17/510 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709321; called by muse, mutect2
- DCAF12L2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as rs776786261, COSV100758920, COSV63581726; called by muse, mutect2, varscan2
- DCHS1 | c.4496G>A p.R1499H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1394524929; called by muse, mutect2, varscan2
- DCHS1 | c.4261C>T p.R1421* | Nonsense Mutation (SNP) | VAF 68/330 reads (21%) | catalogued as rs1179112313; called by muse, mutect2, varscan2
- DCHS2 | c.1853T>A p.I618N | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as rs961145237; called by muse, varscan2
- DCLK2 | c.2239del p.H747Tfs*153 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | catalogued as rs751255369; called by mutect2, pindel
- DDR1 | c.1679C>A p.P560Q (on ENST00000324771; = p.P523Q on NM_001954.4) | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as COSV61326719; called by muse, varscan2
- DDR1 | c.1738G>A p.V580I (on ENST00000324771; = p.V543I on NM_001954.4) | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs756044614; called by muse, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX42 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63791681; called by muse, mutect2, varscan2
- DDX53 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60069795; called by muse, mutect2, varscan2
- DDX55 | c.825C>T p.S275= | Splice Region (SNP) | VAF 23/147 reads (16%) | catalogued as rs139308305; called by muse, varscan2
- DENND1A | c.2792C>T p.A931V | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.15); catalogued as rs1345746656; called by muse, mutect2, varscan2
- DEPP1 | c.313del p.L105Wfs*71 | Frame Shift Del (DEL) | VAF 45/273 reads (16%) | catalogued as COSV53573503; called by mutect2, pindel, varscan2
- DGKQ | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1163723221; called by muse, mutect2, varscan2
- DHX15 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.885); catalogued as rs780510837; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 14/115 reads (12%) | catalogued as rs373108427; called by mutect2, varscan2
- DIP2C | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55173837; called by muse, mutect2, varscan2
- DIS3L | c.310C>T p.R104* (on ENST00000319212 / NM_001143688.3; = p.R21* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/122 reads (13%) | catalogued as rs755849191; called by muse, mutect2, varscan2
- DKK3 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58869805; called by muse, mutect2, varscan2
- DLG5 | c.3802C>T p.Q1268* | Nonsense Mutation (SNP) | VAF 16/217 reads (7%) | catalogued as rs1432843264; called by muse, mutect2
- DLGAP2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 114/485 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs775453367; called by muse, varscan2
- DLGAP3 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.353); catalogued as COSV52396525; called by muse, mutect2
- DMRT2 | c.805T>C p.F269L | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1405767972; called by muse, mutect2, varscan2
- DMRT3 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV51905998; called by muse, varscan2
- DNAH1 | c.8392C>T p.R2798C | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373852790; called by muse, mutect2, varscan2
- DNAH10 | c.8183T>C p.V2728A (on ENST00000409039; = p.V2667A on NM_207437.3) | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs770336735; called by muse, mutect2, varscan2
- DNAH2 | c.12416A>G p.Q4139R | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs1387379550; called by muse, mutect2, varscan2
- DNAH3 | c.10429C>T p.R3477* | Nonsense Mutation (SNP) | VAF 65/375 reads (17%) | catalogued as rs750184108; called by muse, mutect2, varscan2
- DNAH5 | c.12498T>C p.S4166= | Splice Region (SNP) | VAF 72/420 reads (17%) | catalogued as rs1223784357; called by muse, mutect2, varscan2
- DNAH5 | c.9919G>A p.A3307T | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs757212818, COSV54221930; called by muse, mutect2, varscan2
- DNAH7 | c.8313T>A p.N2771K | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56757605; called by muse, mutect2
- DNAH8 | c.5017G>A p.A1673T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs375461103; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAJB13 | c.475del p.I159Lfs*8 | Frame Shift Del (DEL) | VAF 11/131 reads (8%) | catalogued as rs754363435; called by mutect2, pindel
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNASE1L1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 49/393 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV50011456; called by muse, mutect2, varscan2
- DND1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as rs764223305; called by muse, mutect2, varscan2
- DNM3 | c.2300G>A p.R767H (on ENST00000355305 / NM_001350206.2; = p.R761H on NM_015569.5) | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs779486284, COSV100798099, COSV100798567; called by muse, mutect2, varscan2
- DOCK10 | c.5606C>T p.S1869L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV51349290; called by muse, mutect2
- DOCK10 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs770099671, COSV51353950, COSV99289723; called by muse, mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as rs1239294263; called by mutect2, pindel, varscan2
- DOK4 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs950033864, COSV54674352; called by muse, mutect2, varscan2
- DOP1B | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560805511; called by muse, varscan2
- DPH2 | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1317414614; called by muse, mutect2, varscan2
- DPP6 | c.2533G>A p.E845K (on ENST00000377770 / NM_001364500.2; = p.E783K on NM_001936.5) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.658); catalogued as rs765845327; called by muse, mutect2, varscan2
- DPYSL3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as rs1229645083, COSV58327442; called by muse, mutect2, varscan2
- DRD2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755559594, COSV60760737; called by muse, mutect2, varscan2
- DRP2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758782031, COSV65809493; called by muse, mutect2, varscan2
- DSC2 | c.2402G>A p.G801D | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215462499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG1 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs762963122; called by muse, mutect2, varscan2
- DSG3 | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs1323346295; called by muse, mutect2, varscan2
- DSP | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144539278, COSV65794417; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTNA | c.68-6C>T | Splice Region (SNP) | VAF 54/323 reads (17%) | catalogued as rs1243309715; called by muse, mutect2, varscan2
- DUS2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.174); catalogued as rs148751991, COSV100732507; called by muse, mutect2, varscan2
- EBLN1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 132/476 reads (28%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.987); catalogued as COSV69370456; called by muse, mutect2, varscan2
- EDEM1 | c.196del p.V66Yfs*108 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | catalogued as rs753811182; called by mutect2, pindel
- EHD3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs144717418; called by muse, mutect2, varscan2
- EID3 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs762279529; called by muse, varscan2
- EIF2AK4 | c.4892del p.K1631Rfs*48 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | catalogued as rs1400253542; called by mutect2, pindel, varscan2
- EIF3L | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101094545; called by muse, varscan2
- EIF4B | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.457); catalogued as rs561749624, COSV50402691; called by mutect2, varscan2
- ELAVL2 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV56366915; called by muse, mutect2, varscan2
- ELFN2 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as rs745659288, COSV68744567; called by muse, mutect2, varscan2
- ELMO1 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as COSV100164366, COSV60302254, COSV99068342; called by muse, mutect2, varscan2
- ELP4 | c.1147C>T p.R383* (on ENST00000350638; = p.R382* on NM_019040.5) | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV63357180; called by muse, mutect2, varscan2
- EME1 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs753186689; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs761717176; called by mutect2, varscan2
- ENTPD2 | c.1450C>T p.R484C (on ENST00000355097 / NM_203468.3; = p.R461C on NM_001246.4) | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57075372; called by muse, mutect2, varscan2
- EPB41L3 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 56/533 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); catalogued as COSV59470334; called by muse, mutect2, varscan2
- EPB41L4A | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99814051; called by muse, varscan2
- EPC2 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV51543166; called by muse, mutect2, varscan2
- EPHA8 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542943867, COSV51306495; called by muse, mutect2, varscan2
- EPHB1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67668746; called by muse, mutect2, varscan2
- EPHB3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57806587; called by muse, mutect2, varscan2
- EPHB4 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs536270994; called by muse, mutect2, varscan2
- ERAP1 | c.1871del p.L624* | Frame Shift Del (DEL) | VAF 34/226 reads (15%) | catalogued as rs34212508; called by mutect2, pindel, varscan2
- ERBB4 | c.2012T>C p.F671S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99632696; called by muse, mutect2
- EXOC3L1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1185552038; called by muse, mutect2, varscan2
- EXOC7 | c.1651A>G p.K551E (on ENST00000335146 / NM_001145297.4; = p.K469E on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1423465472; called by muse, mutect2, varscan2
- EXOC7 | c.1186G>A p.D396N (on ENST00000335146 / NM_001145297.4; = p.D314N on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs372862629; called by muse, mutect2, varscan2
- EXPH5 | c.2732C>A p.P911H | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as COSV99762127; called by muse, mutect2, varscan2
- EYA4 | c.1210-5T>C | Splice Region (SNP) | VAF 11/135 reads (8%) | catalogued as COSV100766268; called by muse, mutect2
- F7 | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 87/559 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV100661000; called by muse, mutect2, varscan2
- F7 | c.720del p.T241Pfs*2 | Frame Shift Del (DEL) | VAF 64/372 reads (17%) | catalogued as CM010249; called by mutect2, pindel, varscan2
- F8 | c.2108A>C p.N703T | Missense Mutation (SNP) | VAF 23/353 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as CM0910950; called by muse, mutect2
- FAM110C | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1412530671, COSV100566881, COSV59655660; called by muse, mutect2, varscan2
- FAM120C | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1205801622; called by muse, varscan2
- FAM135B | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs1472477886, COSV52715704, COSV99419747; called by muse, mutect2, varscan2
- FAM160B2 | c.1759A>C p.T587P | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1249956060; called by muse, mutect2, varscan2
- FAM171A2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99522516; called by muse, mutect2, varscan2
- FAM178B | c.578dup p.S194Lfs*41 | Frame Shift Ins (INS) | VAF 14/93 reads (15%) | catalogued as rs748296623; called by mutect2, varscan2
- FAM193B | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs773406068; called by muse, mutect2, varscan2
- FAM20C | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1042913138; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM217A | c.1008C>A p.C336* | Nonsense Mutation (SNP) | VAF 26/164 reads (16%) | catalogued as COSV99212724; called by muse, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.8777C>T p.A2926V | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs377736336; called by muse, mutect2, varscan2
- FAT2 | c.7829A>G p.Y2610C | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1262856734; called by muse, mutect2, varscan2
- FAT4 | c.9487G>A p.E3163K | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs370088878, CM1311052; called by muse, varscan2
- FBP1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 94/444 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV64689207; called by muse, mutect2, varscan2
- FBXO15 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs146975565; called by muse, mutect2
- FBXO2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs953184967, COSV52354119; called by muse, mutect2, varscan2
- FBXO3 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs759650593; called by muse, mutect2, varscan2
- FBXO38 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as COSV99693427; called by muse, mutect2, varscan2
- FBXW7 | c.664C>T p.R222* (on ENST00000281708 / NM_001349798.2; = p.R142* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | catalogued as rs920052554, COSV55897378; called by muse, mutect2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 16/73 reads (22%) | catalogued as rs750132652; called by mutect2, pindel, varscan2
- FCGBP | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 73/432 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs758201482; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs777372807; called by mutect2, varscan2
- FLG | c.10199A>G p.H3400R | Missense Mutation (SNP) | VAF 137/675 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs757422482, COSV100911254; called by muse, mutect2, varscan2
- FLNA | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 98/696 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs782538253, COSV100774910, COSV61038660; called by muse, mutect2, varscan2
- FLNA | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 78/667 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as rs782723195; called by muse, mutect2, varscan2
- FLNA | c.2800A>G p.T934A | Missense Mutation (SNP) | VAF 58/509 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs1557178130; called by muse, mutect2, varscan2
- FLYWCH1 | c.1522G>A p.E508K (on ENST00000253928 / NM_001308068.2; = p.E507K on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs779881800, COSV54143791; called by muse, mutect2, varscan2
- FNDC3B | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373434503, COSV100394394; called by muse, mutect2, varscan2
- FOS | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57839653; called by muse, mutect2
- FOXB1 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV68526038; called by muse, mutect2, varscan2
- FOXB1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs867172887; called by muse, mutect2, varscan2
- FOXI1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 40/352 reads (11%) | catalogued as COSV60389285; called by muse, mutect2, varscan2
- FOXI3 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1370585001, COSV101230913; called by muse, mutect2, varscan2
- FOXJ1 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs768830919, COSV99487286; called by muse, varscan2
- FOXJ2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV50817885; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 35/168 reads (21%) | catalogued as rs760347049; called by mutect2, varscan2
- FOXO1 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs757585400; called by muse, mutect2, varscan2
- FRAT2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs775671696; called by muse, varscan2
- FTSJ3 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs575324266; called by muse, mutect2, varscan2
- FUT8 | c.1249G>A p.A417T (on ENST00000360689 / NM_001371534.1; = p.A254T on NM_004480.4) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs1242362970; called by muse, mutect2, varscan2
- FYN | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991512; called by muse, mutect2, varscan2
- FZD9 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs782497063, COSV100750964; called by muse, mutect2
- GABRA1 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1429197938; called by muse, mutect2, varscan2
- GAL3ST3 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV61749241; called by muse, mutect2, varscan2
- GALNT15 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs745413922; called by muse, mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GCC2 | c.1681A>G p.I561V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs371790236; called by mutect2, varscan2
- GCN1 | c.3633G>A p.R1211= | Splice Region (SNP) | VAF 29/194 reads (15%) | catalogued as COSV56108562; called by muse, mutect2, varscan2
- GDF6 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1334355335; called by muse, mutect2, varscan2
- GET3 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs930973539, COSV54406816; called by muse, mutect2, varscan2
- GFY | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs1202221616, COSV54529046; called by muse, mutect2, varscan2
- GIT2 | c.2216C>T p.A739V (on ENST00000355312 / NM_057169.5; = p.A661V on NM_014776.5) | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs1165064238, COSV58083342; called by muse, mutect2, varscan2
- GJA8 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 46/422 reads (11%) | catalogued as COSV53789902; called by mutect2, pindel, varscan2
- GJD2 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV51747675; called by muse, mutect2, varscan2
- GLI1 | c.671_672dup p.E225Rfs*56 | Frame Shift Ins (INS) | VAF 21/157 reads (13%) | catalogued as rs1566559797; called by mutect2, varscan2
- GLI2 | c.3346G>A p.A1116T (on ENST00000361492 / NM_001374353.1; = p.A1133T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/835 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs745719628; called by muse, mutect2, varscan2
- GLI2 | c.4193C>T p.A1398V (on ENST00000361492 / NM_001374353.1; = p.A1415V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58049301; called by muse, mutect2, varscan2
- GLI3 | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 88/625 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); catalogued as rs116840739; called by mutect2, varscan2
- GLIS1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs549929631, COSV56543467; called by muse, mutect2, varscan2
- GNB5 | c.736G>A p.A246T (on ENST00000261837 / NM_016194.4; = p.A204T on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99953234; called by muse, mutect2, varscan2
- GNG13 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs376539534; called by muse, mutect2, varscan2
- GPER1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.036); catalogued as rs766104171; called by muse, mutect2, varscan2
- GPHN | c.1580G>A p.R527H (on ENST00000315266 / NM_001377519.1; = p.R560H on NM_020806.5) | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1364702887; called by muse, varscan2
- GPR157 | c.276C>A p.S92R | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66233338; called by muse, mutect2, varscan2
- GPR31 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 76/493 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as COSV100834101; called by muse, mutect2, varscan2
- GPR88 | c.306del p.A103Qfs*34 | Frame Shift Del (DEL) | VAF 71/427 reads (17%) | catalogued as rs1557852634; called by mutect2, pindel, varscan2
- GPR89B | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs782621260; called by muse, mutect2
- GRB14 | c.1023+2T>C p.X341_splice | Splice Site (SNP) | VAF 10/81 reads (12%) | catalogued as COSV55739585; called by muse, mutect2, varscan2
- GRHL3 | c.1736del p.P579Hfs*11 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs1207812332; called by mutect2, pindel, varscan2
- GRID1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs893024275; called by muse, mutect2, varscan2
- GRIN1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747555101; called by muse, mutect2, varscan2
- GRK6 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs772223816; called by muse, mutect2, varscan2
- GRM3 | c.579del p.D194Tfs*23 | Frame Shift Del (DEL) | VAF 56/290 reads (19%) | catalogued as rs1470079689; called by mutect2, varscan2
- GRM5 | c.2773C>G p.R925G (on ENST00000305447 / NM_001143831.2; = p.R893G on NM_000842.4) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.144); catalogued as rs770092591, COSV59633026; called by muse, mutect2, varscan2
- GSDME | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs377050475; called by muse, mutect2, varscan2
- GSR | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1414576449, COSV104378539; called by muse, mutect2, varscan2
- GTF2A1 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as rs781681151, COSV99993428; called by muse, mutect2, varscan2
- GTF2F1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs1454074232, COSV66725529; called by mutect2, varscan2
- GUCY1A2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs765520349, COSV56479357, COSV99976720; called by muse, mutect2, varscan2
- GUCY2D | c.144del p.A49Pfs*36 | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | catalogued as rs1567956946; called by mutect2, pindel, varscan2
- H2BC18 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as rs782154583; called by muse, mutect2
- H3-4 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1273784037; called by muse, mutect2
- HACL1 | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 31/162 reads (19%) | catalogued as COSV100329848; called by muse, mutect2, varscan2
- HCFC1 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60073733; called by muse, mutect2
- HCN4 | c.3536del p.P1179Lfs*2 | Frame Shift Del (DEL) | VAF 29/263 reads (11%) | catalogued as COSV56083014; called by mutect2, pindel, varscan2
- HCN4 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1207487211, COSV56085443; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HELZ2 | c.4676G>A p.R1559H (on ENST00000467148 / NM_001037335.2; = p.R990H on NM_033405.3) | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377343386; called by muse, mutect2, varscan2
- HERC2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1342400249; called by muse, mutect2, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HIC2 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 53/453 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs750537109; called by muse, mutect2, varscan2
- HIC2 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101335591, COSV68041728; called by muse, mutect2, varscan2
- HIPK4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767437240, COSV52520008; called by muse, mutect2, varscan2
- HIVEP3 | c.6331C>T p.R2111W | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs371175921; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 32/318 reads (10%) | catalogued as rs199474609; called by mutect2, varscan2
- HLA-G | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 118/660 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs901286567, COSV64405663; called by muse, mutect2, varscan2
- HMGCLL1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.393); catalogued as COSV99233165; called by muse, mutect2
- HNF1B | c.840del p.S281Pfs*46 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | catalogued as CD104576; called by mutect2, pindel, varscan2
- HOXA4 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs770446738; called by muse, mutect2
- HS3ST5 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.499); catalogued as rs767501144, COSV57140913; called by muse, mutect2, varscan2
- HSPA12A | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.886); catalogued as rs781799434; called by muse, mutect2, varscan2
- HTR3A | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55472097; called by muse, mutect2, varscan2
- HYDIN | c.4295A>G p.N1432S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1411911642; called by muse, varscan2
- ICAM5 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376339217; called by muse, mutect2, varscan2
- ICE1 | c.1033T>C p.S345P | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99663489; called by muse, varscan2
- IDH3G | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782671638, COSV54207621; called by muse, mutect2, varscan2
- IFT172 | c.5075C>A p.P1692H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99275361; called by muse, varscan2
- IFT172 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs779152335, COSV53131510; called by muse, mutect2, varscan2
- IFT74 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66287642; called by muse, varscan2
- IGF1R | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 50/510 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1441621301, COSV51271348; called by muse, varscan2
- IGF2R | c.2587G>A p.G863S | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs776307638, COSV100808268; called by muse, mutect2, varscan2
- IGFN1 | c.1114del p.A372Hfs*157 (on ENST00000295591 / NM_001367841.1; = p.A372Hfs*86 on NM_001164586.2) | Frame Shift Del (DEL) | VAF 46/305 reads (15%) | catalogued as rs1312622268; called by pindel, varscan2
- IGHV3-21 | c.163T>C p.W55R | Missense Mutation (SNP) | VAF 68/454 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as rs1555459208; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as rs763040860; called by muse, mutect2, varscan2
- IGSF21 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs750165722, COSV52138814; called by muse, varscan2
- IL11 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1274717161; called by muse, mutect2, varscan2
- IL12RB2 | c.1855G>T p.G619C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52025481; called by muse, mutect2, varscan2
- IL25 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559504576, COSV100198062, COSV59306076; called by muse, mutect2, varscan2
- IL27 | c.31+1del p.X11_splice | Splice Site (DEL) | VAF 16/90 reads (18%) | catalogued as COSV63559654; called by mutect2, pindel, varscan2
- IL2RB | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as rs147866253, COSV53427258; called by muse, mutect2, varscan2
- IL4 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99184996; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 125/719 reads (17%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INPP5J | c.1688C>T p.A563V (on ENST00000331075 / NM_001284285.2; = p.A195V on NM_001002837.2) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474656992; called by muse, mutect2, varscan2
- INPP5K | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs144837901; called by muse, mutect2
- INPPL1 | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776269568; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPO8 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1234764565, COSV56240724; called by muse, mutect2, varscan2
- IPP | c.424del p.I142Ffs*42 | Frame Shift Del (DEL) | VAF 36/242 reads (15%) | catalogued as COSV63431859; called by mutect2, pindel, varscan2
- IRF9 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943150166, COSV60702801; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | catalogued as rs761880048; called by mutect2, varscan2
- ITGAD | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1450753343; called by muse, mutect2, varscan2
- ITGAX | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs559233176, COSV51649221; called by muse, mutect2, varscan2
- ITGB1BP1 | c.532-2A>G p.X178_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | catalogued as rs1238239613; called by mutect2, varscan2
- ITGB4 | c.3348G>A p.M1116I | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1374736436; called by muse, mutect2, varscan2
- ITIH6 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV54491294; called by mutect2, varscan2
- ITPR1 | c.6853G>A p.V2285I (on ENST00000354582; = p.V2230I on NM_002222.7) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs779313917, COSV56986620; called by muse, mutect2, varscan2
- ITPR3 | c.4525C>A p.L1509I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as COSV65409512; called by muse, mutect2, varscan2
- ITPRIPL2 | c.414del p.S139Pfs*140 | Frame Shift Del (DEL) | VAF 33/219 reads (15%) | catalogued as rs761100308; called by mutect2, pindel, varscan2
- ITSN1 | c.4040C>T p.T1347M | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs781233789, COSV67157087; called by muse, varscan2
- JAKMIP1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781386208, COSV51537374; called by muse, mutect2, varscan2
- JKAMP | c.652G>A p.V218M (on ENST00000554271 / NM_001284201.1; = p.V204M on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs749452942; called by mutect2, varscan2
- JPH3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199923310, COSV52466294; called by muse, mutect2, varscan2
- JRK | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs587604633; called by muse, mutect2, varscan2
- KALRN | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770918810; called by muse, mutect2, varscan2
- KANSL2 | c.572_574del p.E191del | In Frame Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs1308225589; called by pindel, varscan2
- KAT6A | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs997918495; called by muse, mutect2, varscan2
- KAT6A | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1471098185; called by muse, mutect2, varscan2
- KATNB1 | c.1718+4C>T | Splice Region (SNP) | VAF 38/236 reads (16%) | catalogued as rs782807191; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 31/180 reads (17%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNG1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981554195, COSV65368451; called by muse, mutect2, varscan2
- KCNJ1 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.875); catalogued as rs1407978666; called by muse, mutect2, varscan2
- KCNK10 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs1444705240, COSV100067793; called by muse, mutect2, varscan2
- KCNK16 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs758989727; called by muse, mutect2, varscan2
- KCNMA1 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as rs747439459; called by muse, mutect2, varscan2
- KCNMA1 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM125345; called by muse, mutect2, varscan2
- KCNQ5 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372957711; called by mutect2, varscan2
- KDF1 | c.408del p.S137Afs*111 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | catalogued as rs752617278; called by pindel, varscan2
- KDM2B | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs1555288860; called by muse, mutect2, varscan2
- KIAA1328 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV54455579; called by muse, mutect2, varscan2
- KIAA1586 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1357119738, COSV66057432; called by muse, mutect2, varscan2
- KIAA1614 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs773220681; called by muse, mutect2
- KIAA1671 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as rs1195150085; called by muse, mutect2, varscan2
- KIF21B | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.066); catalogued as rs145500432; called by muse, mutect2, varscan2
- KIF24 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs564380896; called by muse, mutect2, varscan2
- KIF26A | c.5630C>T p.P1877L | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs766668361; called by muse, varscan2
- KIF26B | c.5455C>T p.R1819W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs546302863; called by muse, mutect2, varscan2
- KIF27 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.539); catalogued as rs748681327, COSV99927119; called by muse, mutect2, varscan2
- KIF4B | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200320925; called by muse, mutect2, varscan2
- KIF4B | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs779418962, COSV70528262; called by muse, mutect2, varscan2
- KIF5C | c.9T>A p.D3E | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1488632266; called by muse, mutect2
- KIFAP3 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs199699281; called by muse, mutect2, varscan2
- KIFC1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs749380644; called by muse, mutect2, varscan2
- KIR3DL1 | c.779del p.G260Efs*83 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | catalogued as rs748477568; called by mutect2, pindel, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLHL25 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61995848; called by muse, mutect2, varscan2
- KLHL3 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769995865, COSV59055050; called by muse, mutect2, varscan2
- KLHL34 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.425); catalogued as COSV65280223; called by muse, varscan2
- KLHL36 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as rs763314913; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | catalogued as COSV52930337; called by mutect2, varscan2
- KMT2A | c.5564G>A p.R1855Q | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs377588214, COSV63291979; called by muse, mutect2, varscan2
- KMT2C | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs757111455, COSV51276478, COSV51437196; called by muse, mutect2, varscan2
- KPRP | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 62/413 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs746888694; called by muse, mutect2, varscan2
- KRT32 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs374925222, COSV56785924; called by muse, mutect2, varscan2
- KRT6B | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs376429278; called by muse, mutect2, varscan2
- KRT73 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs114162070, COSV59839418; called by muse, mutect2, varscan2
- KRTAP12-1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.255); catalogued as rs782578288; called by muse, mutect2, varscan2
- KRTAP4-9 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs1484760976, COSV66950663; called by muse, mutect2, varscan2
- KRTAP9-2 | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.875); catalogued as COSV66647036; called by mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 28/190 reads (15%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA1 | c.3263T>C p.V1088A | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as rs1204542594; called by muse, mutect2, varscan2
- LAMA1 | c.2053T>C p.L685= | Splice Region (SNP) | VAF 32/296 reads (11%) | catalogued as rs759860964; called by muse, mutect2, varscan2
- LAMA2 | c.2049_2050del p.R683Sfs*21 | Frame Shift Del (DEL) | VAF 66/440 reads (15%) | catalogued as rs202247790; called by pindel, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDB3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 78/462 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs61857115; ClinVar: uncertain significance; called by muse, varscan2
- LHB | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 98/688 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs746167425, COSV99669256; called by muse, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 14/134 reads (10%) | catalogued as rs775423572; called by mutect2, varscan2
- LILRA1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs529375145, COSV52184940; called by muse, varscan2
- LIPT2 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs901197909; called by muse, mutect2, varscan2
- LMAN1L | c.381del p.L128Wfs*75 | Frame Shift Del (DEL) | VAF 12/105 reads (11%) | catalogued as COSV59003665; called by mutect2, pindel, varscan2
- LOXL2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763353774, COSV66690379; called by muse, mutect2, varscan2
- LPCAT1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 89/557 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV99359246; called by muse, mutect2, varscan2
- LPP | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs751169575; called by muse, varscan2
- LRBA | c.6020C>T p.A2007V | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1318451576; called by muse, mutect2
- LRFN2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 46/372 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs372798702; called by muse, mutect2, varscan2
- LRFN5 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV99985062; called by muse, mutect2, varscan2
- LRIG2 | c.225dup p.D76Rfs*10 | Frame Shift Ins (INS) | VAF 32/223 reads (14%) | catalogued as rs768751013; called by mutect2, pindel, varscan2
- LRIG2 | c.670_674del p.R224Qfs*3 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs780035544; called by mutect2, pindel, varscan2
- LRIT1 | c.161del p.P54Rfs*114 | Frame Shift Del (DEL) | VAF 27/180 reads (15%) | catalogued as rs1370241998; called by mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 66/363 reads (18%) | catalogued as rs139915490; called by mutect2, varscan2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP2 | c.11807G>A p.G3936D | Missense Mutation (SNP) | VAF 81/501 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.744); catalogued as COSV99788549; called by muse, mutect2, varscan2
- LRP2 | c.8448T>A p.N2816K | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55539596; called by muse, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 45/265 reads (17%) | catalogued as COSV55542953; called by muse, mutect2, varscan2
- LRP5 | c.1833del p.C612Afs*23 | Frame Shift Del (DEL) | VAF 90/491 reads (18%) | catalogued as CM053295, CM053961; called by mutect2, pindel, varscan2
- LRP5 | c.3454G>T p.A1152S | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53712391; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC38 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1156570726; called by muse, mutect2, varscan2
- LRRC4 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 122/609 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs200804366, COSV50813271; called by muse, mutect2, varscan2
- LRRC66 | c.856G>T p.G286W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs570531379, COSV100602956; called by muse, mutect2, varscan2
- LRRC8B | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58374074; called by muse, mutect2
- LRRN4CL | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 88/460 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99628554; called by muse, mutect2, varscan2
- LTBP2 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs767990421; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- MAB21L3 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201318222; called by muse, mutect2, varscan2
- MAD2L1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs758740535, COSV99633797; called by mutect2, varscan2
- MAGIX | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 117/737 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.221); catalogued as COSV66255700; called by muse, mutect2, varscan2
- MAML3 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs935950874, COSV72210390; called by muse, mutect2, varscan2
- MAN2B1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 140/774 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD124176, COSV54418465; called by muse, mutect2, varscan2
- MAP1A | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as COSV55498429; called by muse, mutect2, varscan2
- MAP1S | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779553894; called by muse, mutect2, varscan2
- MAP3K1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as COSV68125794; called by muse, mutect2, varscan2
- MAP3K21 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1484902101; called by muse, mutect2
- MAP3K4 | c.4574C>T p.A1525V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199760724, COSV62330291; called by mutect2, varscan2
- MAP4K1 | c.2341-7del | Splice Region (DEL) | VAF 12/107 reads (11%) | catalogued as rs767461672, COSV101204269; called by mutect2, pindel, varscan2
- MARCHF2 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 89/412 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs1314708175, COSV99294849; called by muse, mutect2, varscan2
- MARCHF5 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62769763; called by muse, mutect2, varscan2
- MARK2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59286957; called by muse, mutect2, varscan2
- MARK2 | c.2258G>A p.C753Y (on ENST00000402010 / NM_001039469.2; = p.C689Y on NM_004954.5) | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851884; called by muse, mutect2, varscan2
- MAST3 | c.3619G>A p.G1207R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1280899655; called by muse, mutect2, varscan2
- MAST4 | c.7850G>A p.S2617N (on ENST00000403625 / NM_001164664.2; = p.S2428N on NM_015183.3) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.233); catalogued as rs773935343; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as rs746267361; called by mutect2, varscan2
- MCM9 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs768968338; called by muse, mutect2, varscan2
- MCOLN3 | c.129A>T p.K43N | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs776400176, COSV62013260; called by muse, varscan2
- MDGA1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs1445924952; called by muse, mutect2, varscan2
- MDH2 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs1194543391; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs750092100; called by mutect2, varscan2
- MED13L | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 37/328 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1196211816; called by muse, varscan2
- MEF2D | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs756769571; called by muse, mutect2, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 70/384 reads (18%) | catalogued as rs759225724, COSV53895347; called by mutect2, varscan2
- MEGF8 | c.3626G>A p.R1209Q (on ENST00000251268 / NM_001271938.2; = p.R1142Q on NM_001410.3) | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs556378666; called by muse, mutect2, varscan2
- MEGF9 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs777877153; called by muse, mutect2, varscan2
- MEPCE | c.434del p.G145Afs*11 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs760012501; called by mutect2, varscan2
- MFHAS1 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.261); catalogued as rs1003261373; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD5 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs762649843, COSV100289098; called by muse, mutect2, varscan2
- MFSD6 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55623501; called by muse, mutect2, varscan2
- MFSD6L | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV61004438; called by muse, mutect2, varscan2
- MGAM | c.2724G>T p.E908D | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72075079; called by muse, mutect2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 51/339 reads (15%) | catalogued as COSV55498546; called by mutect2, pindel, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIDN | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs1339718301; called by muse, mutect2, varscan2
- MINK1 | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as rs576676808, COSV53418544; called by muse, mutect2, varscan2
- MKI67 | c.1941_1943del p.R647del | In Frame Del (DEL) | VAF 32/122 reads (26%) | catalogued as rs772499094; called by pindel, varscan2
- MLH3 | c.1835T>C p.V612A | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs767938226; called by muse, mutect2, varscan2
- MLYCD | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as rs1044258796; called by muse, mutect2, varscan2
- MME | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs778011002; called by muse, mutect2, varscan2
- MMP20 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 47/328 reads (14%) | catalogued as COSV52775329; called by muse, mutect2, varscan2
- MMP25 | c.1444C>A p.H482N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs748257213; called by muse, mutect2, varscan2
- MN1 | c.246del p.L83Cfs*140 | Frame Shift Del (DEL) | VAF 23/136 reads (17%) | catalogued as COSV56557060; called by mutect2, pindel, varscan2
- MOCS1 | c.1718A>G p.H573R | Missense Mutation (SNP) | VAF 69/515 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.67); catalogued as rs1195442940; called by muse, mutect2, varscan2
- MOSPD1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs757234804; called by muse, mutect2, varscan2
- MPL | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 83/513 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs368753117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRGPRX3 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs370102882; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL52 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs542832940; called by muse, mutect2, varscan2
- MRTFB | c.2332G>A p.A778T (on ENST00000571589 / NM_001365412.2; = p.A728T on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs768200307, COSV100371220, COSV57957805; called by muse, mutect2, varscan2
- MS4A10 | c.295del p.A99Lfs*12 | Frame Shift Del (DEL) | VAF 43/238 reads (18%) | catalogued as rs1407636693; called by mutect2, pindel, varscan2
- MSI1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.973); catalogued as rs976626221; called by muse, mutect2, varscan2
- MTCL1 | c.4714del p.A1572Hfs*28 (on ENST00000306329 / NM_001378206.1; = p.A1253Hfs*28 on NM_015210.4) | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as rs1209504789; called by mutect2, pindel, varscan2
- MTHFD1L | c.278del p.N93Tfs*18 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs769597461; called by mutect2, pindel, varscan2
- MTM1 | c.397A>T p.M133L | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as CD972337; called by muse, mutect2, varscan2
- MTM1 | c.594C>A p.Y198* | Nonsense Mutation (SNP) | VAF 43/311 reads (14%) | catalogued as CM990870; called by muse, mutect2, varscan2
- MTSS1 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240541434, COSV52676393; called by muse, mutect2, varscan2
- MUTYH | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as rs369410616; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MUTYH | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 109/736 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1374712964; called by muse, mutect2, varscan2
- MXRA5 | c.2690A>G p.E897G | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1367101357; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 138/346 reads (40%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH14 | c.4886G>A p.R1629H | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759824498, COSV51815031; called by muse, mutect2, varscan2
- MYH4 | c.5050C>G p.L1684V | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1295025549; called by muse, mutect2, varscan2
- MYL2 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99960891; called by muse, mutect2, varscan2
- MYO18B | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.031); catalogued as rs371265439; called by muse, mutect2, varscan2
- MYO18B | c.6592C>T p.R2198C | Missense Mutation (SNP) | VAF 68/509 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs372977526, COSV59151186; called by muse, mutect2, varscan2
- MYO1A | c.3102del p.S1035Vfs*6 | Frame Shift Del (DEL) | VAF 16/127 reads (13%) | catalogued as rs777575982; called by mutect2, pindel, varscan2
- MYO5A | c.4750C>T p.R1584C | Missense Mutation (SNP) | VAF 90/534 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1441544634, COSV62560710; called by muse, mutect2, varscan2
- MYOD1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as COSV100000522; called by muse, mutect2, varscan2
- MYOM3 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs367570862; called by muse, mutect2, varscan2
- MYRIP | c.1632del p.S545Afs*7 | Frame Shift Del (DEL) | VAF 25/196 reads (13%) | catalogued as COSV56870613; called by mutect2, pindel, varscan2
- NAALADL2 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457448528; called by muse, mutect2
- NADSYN1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs117905259; called by muse, mutect2, varscan2
- NAXE | c.326del p.P109Lfs*47 | Frame Shift Del (DEL) | VAF 49/233 reads (21%) | catalogued as rs779820587; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NBEA | c.3953G>A p.R1318H | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59762766; called by muse, mutect2, varscan2
- NBEAL2 | c.4108A>G p.T1370A | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs964829875; called by muse, mutect2, varscan2
- NCF1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 74/460 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1554413140; called by muse, mutect2, varscan2
- NCKAP1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376970668; called by muse, mutect2, varscan2
- NCOR2 | c.5627A>G p.H1876R | Missense Mutation (SNP) | VAF 90/441 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs760022821, COSV62299861; called by muse, mutect2, varscan2
- NCR3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 91/481 reads (19%) | catalogued as rs1280852176, COSV53002558; called by muse, mutect2, varscan2
- NDUFA5 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63251771; called by muse, mutect2, varscan2
- NEB | c.7729T>C p.S2577P | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99427990; called by muse, mutect2, varscan2
- NEIL1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 84/471 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs764632635; called by muse, mutect2, varscan2
- NEU1 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as CM040097; called by muse, mutect2, varscan2
- NEU4 | c.271C>T p.H91Y (on ENST00000391969 / NM_001167602.3; = p.H103Y on NM_080741.4) | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1251539923; called by muse, mutect2, varscan2
- NKPD1 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1358231793; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX2-3 | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755110; called by muse, mutect2
- NLGN3 | c.2242C>T p.R748W (on ENST00000358741 / NM_181303.2; = p.R728W on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs1411509097; called by muse, mutect2, varscan2
- NLRP1 | c.4279C>T p.R1427W (on ENST00000572272 / NM_033004.4; = p.R1383W on NM_014922.5) | Missense Mutation (SNP) | VAF 90/535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754014640, COSV52566950, COSV99335467; called by muse, mutect2, varscan2
- NLRP1 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199748129, COSV52563658, COSV52572656; called by muse, mutect2, varscan2
- NLRP12 | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs759172362; called by muse, mutect2, varscan2
- NLRP7 | c.2695C>T p.L899F (on ENST00000340844 / NM_206828.3; = p.L871F on NM_139176.3) | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60179647; called by muse, mutect2, varscan2
- NMUR2 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV54923095; called by muse, mutect2
- NOC4L | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1203487380; called by muse, mutect2
- NOL4L | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62889136; called by muse, mutect2, varscan2
- NOP14 | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 42/229 reads (18%) | catalogued as rs188640033, COSV58627076; called by muse, mutect2, varscan2
- NOTCH1 | c.4372G>A p.A1458T | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200495793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOX5 | c.652del p.R218Afs*10 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs777268755; called by mutect2, pindel, varscan2
- NPAS1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as rs781209604, COSV71383855; called by muse, varscan2
- NPAS4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV60652097; called by mutect2, varscan2
- NPBWR2 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.808); catalogued as rs745888707; called by muse, mutect2, varscan2
- NPC1L1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs777949850; called by muse, mutect2, varscan2
- NPTX2 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55717322; called by muse, mutect2
- NR5A1 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 102/557 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs981580861, COSV65294564; called by mutect2, varscan2
- NRBP2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs369824128; called by muse, mutect2, varscan2
- NRP1 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs554872876, COSV55171299; called by muse, mutect2, varscan2
- NRXN1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68029352; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTMT1 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1194885440; called by muse, mutect2, varscan2
- NTRK2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs144037140; called by muse, mutect2, varscan2
- NUP188 | c.4137G>T p.Q1379H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV65362512; called by muse, mutect2, varscan2
- NUP210 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286848851; called by muse, mutect2, varscan2
- NWD2 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 54/436 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as rs1426117421; called by muse, varscan2
- NYAP2 | c.945dup p.K316Qfs*116 | Frame Shift Ins (INS) | VAF 32/191 reads (17%) | catalogued as rs758750309; called by mutect2, varscan2
- OBP2A | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 52/363 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs369119006; called by muse, mutect2, varscan2
- OBSCN | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 75/552 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs1345412932; called by muse, mutect2, varscan2
- OLFM2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs1223842673, COSV53431824; called by muse, mutect2, varscan2
- OLIG2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1335709971; called by muse, mutect2, varscan2
- OR10H1 | c.938A>G p.E313G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV58470587; called by muse, mutect2
- OR12D3 | c.180dup p.L61Sfs*59 | Frame Shift Ins (INS) | VAF 26/120 reads (22%) | catalogued as rs762417164; called by mutect2, varscan2
- OR13C9 | c.84del p.F28Lfs*3 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | catalogued as rs865891766; called by mutect2, pindel, varscan2
- OR13J1 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 76/359 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs752418709; called by muse, mutect2, varscan2
- OR4D2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 140/920 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.12); catalogued as rs1199201337; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 23/247 reads (9%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 37/193 reads (19%) | catalogued as rs1564877761; called by mutect2, varscan2
- OR52J3 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as rs146387387; called by muse, mutect2, varscan2
- OR5AR1 | c.924del p.K308Nfs*8 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1179572364; called by mutect2, pindel, varscan2
- OR5H1 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV63403280; called by muse, mutect2, varscan2
- OR6K2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs913038867; called by muse, mutect2, varscan2
- OR7A17 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1358613719; called by muse, mutect2, varscan2
- OR9Q2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 84/369 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs752846977, COSV61111786; called by muse, mutect2, varscan2
- OSM | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs199694620, COSV53161433; called by muse, mutect2, varscan2
- OXCT2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.284); catalogued as COSV59593446; called by muse, mutect2, varscan2
- P3H1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 85/586 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370255593; called by muse, mutect2, varscan2
- PALLD | c.2239G>T p.D747Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs991371952; called by muse, mutect2, varscan2
- PAQR9 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV61418160; called by muse, mutect2
- PARP14 | c.2683T>C p.Y895H | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV101506205; called by muse, mutect2
- PARP16 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs150509568; called by muse, mutect2, varscan2
- PATJ | c.3002A>G p.D1001G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs778283378; called by muse, mutect2, varscan2
- PATJ | c.3490C>T p.R1164* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as rs370890473; called by muse, mutect2, varscan2
- PCDH10 | c.251T>C p.I84T | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52106395; called by muse, mutect2, varscan2
- PCDH10 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs1166212333, COSV99993065; called by muse, mutect2, varscan2
- PCDH15 | c.3441del p.K1147Nfs*20 | Frame Shift Del (DEL) | VAF 28/264 reads (11%) | catalogued as COSV100225432; called by pindel, varscan2
- PCDH7 | c.2056del p.S686Lfs*47 | Frame Shift Del (DEL) | VAF 40/381 reads (10%) | catalogued as COSV100688790; called by mutect2, varscan2
- PCDHA1 | c.304T>C p.C102R | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100974306; called by mutect2, varscan2
- PCDHA12 | c.2196C>A p.C732* | Nonsense Mutation (SNP) | VAF 38/298 reads (13%) | catalogued as rs782433528, COSV99165495; called by mutect2, varscan2
- PCDHA7 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 108/575 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.417); catalogued as COSV65341833; called by muse, mutect2, varscan2
- PCDHB9 | c.1176del p.L393* | Frame Shift Del (DEL) | VAF 43/403 reads (11%) | catalogued as rs782200278; called by mutect2, pindel, varscan2
- PCDHB9 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 180/1208 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as rs782490536, COSV53377046; called by muse, mutect2, varscan2
- PCDHGB2 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs569018820; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 41/286 reads (14%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCLO | c.15188del p.K5063Rfs*2 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs1405726136; called by mutect2, pindel, varscan2
- PCMTD2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs201257903, COSV99829545; called by muse, mutect2, varscan2
- PCSK4 | c.1874dup p.R626Afs*71 | Frame Shift Ins (INS) | VAF 57/323 reads (18%) | catalogued as rs1174914612; called by mutect2, varscan2
- PDCD6 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as rs1407999951; called by muse, mutect2, varscan2
- PDE3A | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as rs756964543, COSV62975199; called by muse, varscan2
- PDE4D | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as COSV61444078; called by muse, mutect2, varscan2
- PDE4D | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1411722004; called by muse, varscan2
- PDLIM4 | c.327+8C>T | Splice Region (SNP) | VAF 30/162 reads (19%) | catalogued as rs1043272008; called by muse, mutect2, varscan2
- PELP1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs540770637; called by muse, mutect2, varscan2
- PER1 | c.1396del p.L466* | Frame Shift Del (DEL) | VAF 38/271 reads (14%) | catalogued as rs773913770; called by mutect2, varscan2
- PEX1 | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV50395336; called by muse, mutect2, varscan2
- PEX1 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); catalogued as COSV99951777; called by muse, mutect2, varscan2
- PGGHG | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1387159265; called by muse, mutect2, varscan2
- PGLS | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs746222175; called by muse, mutect2, varscan2
- PGR | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 66/545 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1279278874, COSV54799903; called by muse, mutect2, varscan2
- PHF10 | c.543+1G>A p.X181_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as rs1204195853; called by muse, mutect2, varscan2
- PHF2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771361962, COSV100823200, COSV63680000; called by muse, mutect2, varscan2
- PHF2 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs138985054; called by muse, varscan2
- PHF20L1 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1372237318; called by muse, mutect2, varscan2
- PHKA1 | c.2825C>T p.A942V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59812615; called by muse, mutect2
- PHLDB1 | c.3754G>A p.V1252M | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782567996; called by muse, mutect2, varscan2
- PIAS1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV51030754; called by muse, mutect2, varscan2
- PIAS3 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs137979084; called by muse, mutect2, varscan2
3,376 further variants in this file (2,047 protein-altering or splice-affecting, 839 silent, 490 other) are not listed here.
